Somatic mutation profile of tumor specimen MP2PRT-PAVRDA-TMP1-A (aliquot MP2PRT-PAVRDA-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVRDA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,225 days).
Specimen MP2PRT-PAVRDA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8a61424-5e16-4525-a06f-fe509a88df86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRDA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRDA-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4aa119f-83b8-4b1c-8e2a-339243378328

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 71/327 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C2CD5 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61724254; called by muse, mutect2, varscan2
- CACNA1F | c.2914C>T p.R972* | Nonsense Mutation (SNP) | VAF 62/868 reads (7%) | catalogued as CM030202; called by muse, mutect2
- CHRM1 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 46/755 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs762373862; called by muse, mutect2
- CSMD3 | c.5045G>A p.G1682E (on ENST00000297405 / NM_001363185.1; = p.G1578E on NM_052900.3) | Missense Mutation (SNP) | VAF 33/325 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs757326526; called by muse, mutect2, varscan2
- FAM135B | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 179/584 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs372585070; called by muse, mutect2, varscan2
- GABRB1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 79/813 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.503); catalogued as rs144532495, COSV54993120; called by muse, mutect2
- IGSF1 | c.2006C>T p.S669L | Missense Mutation (SNP) | VAF 96/828 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV100812263; called by muse, mutect2, varscan2
- LMLN2 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 65/771 reads (8%) | catalogued as rs1422555702; called by muse, mutect2
- LRRIQ1 | c.828A>T p.K276N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1345733366; called by muse, mutect2
- MMP21 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 66/782 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs970463089; called by muse, mutect2
- MYO9B | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 47/691 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs368425030; called by muse, mutect2
- OR4K1 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 48/790 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs768057389, COSV53459767; called by muse, mutect2
- PTPN14 | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 104/768 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs79745253; called by muse, mutect2, varscan2
- CACNB1 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 36/693 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM83H | c.182T>A p.L61Q | Missense Mutation (SNP) | VAF 336/1082 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- OR8B2 | c.132del p.L45* | Frame Shift Del (DEL) | VAF 48/466 reads (10%) | called by mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 71/528 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AMN1 | c.579G>A p.A193= | Silent (SNP) | VAF 96/253 reads (38%) | catalogued as rs747706961, COSV55671229; called by muse, mutect2
- BASP1 | c.408C>T p.A136= | Silent (SNP) | VAF 300/666 reads (45%) | catalogued as rs754779068; called by muse, mutect2, varscan2
- COL25A1 | c.1296C>T p.N432= | Silent (SNP) | VAF 89/740 reads (12%) | catalogued as rs372574550; called by muse, mutect2, varscan2
- DPP4 | c.216A>G p.Q72= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs147389677; called by muse, mutect2, varscan2
- KNDC1 | c.3765G>A p.P1255= | Silent (SNP) | VAF 64/850 reads (8%) | catalogued as rs771429339; called by muse, mutect2
- MRGPRE | c.192C>T p.D64= | Silent (SNP) | VAF 35/710 reads (5%) | catalogued as rs766159353, COSV67745787; called by muse, mutect2
- PCDH17 | c.1737C>T p.N579= | Silent (SNP) | VAF 74/515 reads (14%) | catalogued as COSV64972042; called by muse, varscan2
- SLC39A2 | c.441C>T p.F147= | Silent (SNP) | VAF 181/914 reads (20%) | catalogued as rs375249363, COSV100068794; called by muse, mutect2, varscan2
- MAMLD1 | c.*321A>G | 3'UTR (SNP) | VAF 273/941 reads (29%) | called by muse, mutect2, varscan2
